Surgical pathology report (de-identified scan), TCGA case TCGA-AJ-A3EJ, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma), tissue source site International Genomics Conosrtium, specimen TCGA-AJ-A3EJ-01A (Primary Tumor).

[page 1 of 4]
Collection Date:
Hospital of Origin:
Copy to:

QC Pathologist:

ICD-O-3 (8380/3) (8441/3)
carcinoma, endometrioid + serous = 8441/3
site: endometrium C54.1
for 10/31/11

FINAL PATHOLOGIC DIAGNOSIS:

A. Left ovary and fallopian tube, excision:

Corpora albicantia.

Serous cysts.

Fallopian tube without significant pathologic abnormality.

B. Right ovary and fallopian tube, excision:

Corpora albicantia.

Serous cysts.

Fallopian tube without significant pathologic abnormality.

Benign paratubal cysts.

C. Uterus, hysterectomy:

Tumor Characteristics:

1. Histologic type: Mixed pattern carcinoma with endometrioid and serous components, predominantly serous, see comment.

2. Histologic grade: 3.

3. Tumor site: Endometrium.

4. Tumor size: 9.5 x 7.5 cm.

5. Myometrial invasion: Tumor extends 1.7 cm into a 2.0 cm thick myometrium.

6. Involvement of cervix: No.

7. Extent of involvement of other organs: None identified.

8. Lymphovascular space invasion: None identified.

Surgical Margin Status:

1. Margins uninvolved: Bilateral parametria, cervix, serosa.

2. Margins involved: None.

Lymph Node Status:

1. See parts D through I, K.

Other:

1. Other significant findings: Uterine wall leiomyomata.

2. Frozen section diagnosis confirmed.

3. pTNM stage: pT1b, N2 (FIGO: IIIC2).

D. Left common iliac and aortic lymph nodes, excision:

Four lymph nodes, negative for metastatic disease.

E. Left obturator lymph nodes, excision:

Seven of seven lymph nodes positive for metastatic carcinoma, high grade.

Size of the large metastasis: 0.6 cm.

Reviewed Initials	Rmt	

[page 2 of 4]
Frozen section diagnosis confirmed.

F. Left external lymph nodes, () ion:

Five lymph nodes, negative for metastatic disease.

G. Left obturator lymph nodes #2, excision:

One of five lymph nodes positive for metastatic carcinoma.

H. Right aortic and common iliac lymph nodes, excision:

Two of seven lymph nodes positive for metastatic carcinoma.

I. Right external lymph nodes, excision:

One of three lymph nodes positive for metastatic carcinoma.

J. Omentum, excision:

Negative for malignancy.

K. Right obturator lymph nodes, excision:

Six lymph nodes, negative for metastatic disease.

COMMENTS:

Appropriately controlled immunohistochemical stains for p53 and estrogen receptor performed on block C6 show majority of lesional cells positive for p53 and estrogen receptor.

These findings are consistent with serous carcinoma.

CLINICAL HISTORY:

Preoperative Diagnosis: Endometrial cancer

Postoperative Diagnosis:

Symptoms/Radiologic Findings:

SPECIMENS:

A. Left tube and ovary

B. Right tube and ovary

C. Uterus, cervix

D. Left common iliac and aortic lymph nodes

E. Left obturator lymph nodes

F. External lymph nodes

G. Left obturator lymph nodes #2

H. Right aortic and common iliac lymph nodes

I. Right external

J. Omentum

K. Right obturator

CODES:

PROCEDURAL DEMOGRAPHICS:

Date of Procedure:

Accession Date/Time:

[page 3 of 4]
GROSS DESCRIPTION:

A. The first container A is labeled #1.
The specimen consists of an ovary with attached fallopian tube. The ovary measures 3.5 x 2.0 x 1.5 cm. The surface is yellow to gray tan. On sectioning there are cysts containing serous fluid, 0.5 and 1.2 cm. There are corpus albicans identified measuring up to 0.5 cm. The fallopian tube measures 3.0 cm in length and up to 0.4 cm in diameter. The surface is gray to brown tan. On sectioning there is no material or lesions identified within the lumen. The fallopian tube appears grossly unremarkable. Representative sections are submitted in cassettes as follows: ovary--1 and 2; fallopian tube--3.

B. The second container B is labeled #2.
The specimen consists of an ovary with attached fallopian tube. The ovary measures 3.0 x 1.0 x 0.5 cm. The surface is yellow gray. On sectioning the cut surface is yellow tan and reveals corpus albicans measuring up to 0.5 cm. The fallopian tube measures 6.0 cm in length and 0.4 cm in diameter. The surface is gray to brown tan. On sectioning there is no material or lesions identified within the lumen. The fallopian tube appears grossly unremarkable. Representative sections are submitted in cassettes as follows: ovary--1 and 2; fallopian tube--3.

C. The third container C is labeled #3.
The specimen consists of a previously bisected uterus with attached cervix. The uterus measures 7.5 x 7.0 x 7.0 cm and weighs 259 grams. The serosal surface is gray tan to brown tan. There is a subserosal nodule measuring 1.0 cm that has a white tan whorled appearance. There is no evidence of hemorrhage or necrosis. The serosal surface has been inked. Sections from the parametrium have been taken. The cervix measures 4.0 cm in length and 3.0 cm in diameter and has a 1.0 cm round patent os. The ectocervix is gray tan to pink tan. The endocervical canal is light tan, a gray tan polypoid lesion, 1.2 cm. There are no other lesions identified. The endometrial cavity measures 7.5 x 8.0 cm and is completely lined by a gray tan nodular shaggy mass measuring 9.5 x 7.5 cm. On sectioning the mass extends into the underlying myometrium approximately 1.7 cm into a 2.0 cm thick myometrium. A section from the mass was examined at the time of surgery. The mass comes within 0.3 cm of the lower uterine segment. Within the myometrium there is also a white tan whorled intramural mass measuring 2.0 cm in greatest dimension. There is no evidence of hemorrhage or necrosis. Received with the specimen are two cassettes, one green and one yellow, labeled Representative sections are submitted in cassettes as follows: frozen section--1; anterior cervix--2; posterior cervix--3; full thickness sections taken from the mass--4 to 8; lower uterine segment--9; left parametrium--10; right parametrium--11; subserosal nodule--12; myometrial mass--13.

D. The fourth container D is labeled left
aortic lymph nodes common iliac. The specimen consists of a

[page 4 of 4]
portion of fibroadipose tissue measuring 4.5 x 2.5 x 1.0 cm. Sectioning reveals four probable lymph nodes measuring from 0.5 to 2.0 cm in greatest dimension. The lymph nodes are entirely submitted in cassettes as follows: two probable nodes--1; one probable node bisected--2; one probable lymph node bisected--3 and 4

E. The fifth container E is labeled left obturator lymph nodes. The specimen consists of a portion of fibroadipose tissue measuring 5.0 x 3.5 x 1.0 cm. Sectioning reveals lymphoid fragments measuring from 0.7 to 1.5 cm. Representative sections were examined at the time of surgery. The lymphoid fragments are subsequently entirely submitted in cassettes as follows: frozen section--1; two pieces--2; one piece sectioned--3; one piece sectioned--4.

F. The sixth container F is labeled left external. The specimen consists of a portion of fibroadipose tissue measuring 5.0 x 4.5 x 1.0 cm. Sectioning reveals five probable lymph nodes measuring from 0.7 to 1.8 cm. The lymph nodes are entirely submitted in cassettes as follows: three probable nodes--1; one probable node bisected--2; one probable lymph node bisected--3 and 4.

G. The seventh container G is labeled left obturator lymph nodes #2. The specimen consists of a portion of fibroadipose tissue measuring 6.0 x 4.5 x 1.0 cm. Sectioning reveals five probable lymph nodes measuring from 0.5 to 4.0 cm. The lymph nodes are entirely submitted in cassettes as follows: two probable nodes--1; one probable node bisected--2; one probable node bisected--3 and 4; one probable node sectioned--5 to 8.

H. The eighth container H is labeled right aortic and common iliac. The specimen consists of a portion of fibroadipose tissue, 4.5 x 4.0 x 1.0 cm. Sectioning reveals seven probable lymph nodes, 0.5 to 1.5 cm. The lymph nodes are entirely submitted in cassettes as follows: three probable nodes--1; two probable nodes--2; one probable node bisected--3; one probable lymph node bisected--4.

I. The ninth container I is labeled right external. The specimen consists of a portion of fibroadipose tissue measuring 5.0 x 2.0 x 1.0 cm. Sectioning reveals three probable lymph nodes measuring from 0.6 to 1.2 cm. The lymph nodes are entirely submitted in cassettes as follows: two probable nodes--1; one probable node bisected--2.

J. The tenth container J is labeled omentum. The specimen consists of a piece of yellow tan lobular fibroadipose omental tissue measuring 40.0 x 14.0 x 2.0 cm. On sectioning there are no nodules grossly identified. Representative sections are submitted in four cassettes.

K. The eleventh container K is labeled The specimen consists of a portion of fibroadipose tissue measuring 7.0 x 3.0 x 1.0 cm. Sectioning reveals six

probable lymph nodes measuring from 0.2 to 4.5 cm. The lymph nodes are entirely submitted in cassettes as follows: one probable node bisected--1; three probable nodes--2; one probable node bisected--3; one probable node sectioned--4 to 9.

Source: NCI Genomic Data Commons file 20ecdc8e-ae0f-4b3b-8f07-43866ba01fc3 (TCGA-AJ-A3EJ.FB99D237-4583-4298-844F-43B2F99F83E3.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).